Somatic mutation profile of tumor specimen TCGA-D6-A4ZB-01A (aliquot TCGA-D6-A4ZB-01A-11D-A25D-08) from TCGA case TCGA-D6-A4ZB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.5 years (22,455 days).
Specimen TCGA-D6-A4ZB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45f61c89-a9e7-47b8-ab86-18354f1a5277.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A4ZB-10A (Blood Derived Normal), aliquot TCGA-D6-A4ZB-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1c63d0c-8a69-46bd-9ffc-3f9ff2a63d24

The open-access MAF lists 148 somatic variants for this specimen: 118 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 27, Nonsense Mutation 10, Splice Site 2, RNA 1, Translation Start Site 1, Frame Shift Del 1, 3'Flank 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.767T>C p.I256T (on ENST00000219054; = p.I177T on NM_001308169.2) | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV99525516; called by muse, mutect2
- ADGRG6 | c.3219G>C p.L1073F | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602483; called by muse, mutect2
- AKAP4 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV62074665; called by muse, mutect2, varscan2
- BAZ2A | c.4906G>C p.E1636Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV51630573, COSV99467173; called by muse, mutect2
- BCAR3 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV99551052; called by muse, mutect2
- BUB1 | c.2005C>G p.H669D | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs759821736, COSV100241505; called by muse, mutect2, varscan2
- C12orf42 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV100172540; called by muse, mutect2
- C5 | c.4292G>A p.G1431E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99798431; called by muse, mutect2, varscan2
- C6orf118 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.569); catalogued as COSV100024854; called by muse, mutect2, varscan2
- CADPS2 | c.2824A>C p.M942L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100464839; called by muse, mutect2, varscan2
- CASD1 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99802888; called by muse, mutect2
- CCDC173 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV71653448; called by muse, mutect2, varscan2
- CCNT2 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99751012; called by muse, mutect2
- CEP152 | c.3933G>A p.M1311I (on ENST00000380950 / NM_001194998.2; = p.M1255I on NM_014985.4) | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100359029; called by muse, mutect2
- CEP44 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV99639653; called by muse, mutect2, varscan2
- CLK2 | c.847G>C p.D283H (on ENST00000368361 / NM_001294339.2; = p.D282H on NM_003993.4) | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV100226853, COSV56944706; called by muse, mutect2
- CLSTN2 | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV101515850; called by muse, mutect2, varscan2
- CSMD2 | c.1772C>G p.S591C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763664291, COSV99593239; called by muse, mutect2, varscan2
- CSMD3 | c.7253T>A p.I2418N (on ENST00000297405 / NM_001363185.1; = p.I2314N on NM_052900.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52214184; called by muse, mutect2, varscan2
- CSMD3 | c.3528A>C p.E1176D (on ENST00000297405 / NM_001363185.1; = p.E1072D on NM_052900.3) | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99842536; called by muse, mutect2
- CTNNA2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.388); catalogued as COSV100781807; called by muse, mutect2, varscan2
- CYC1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs968965290, COSV100010540; called by muse, mutect2
- CYP1B1 | c.1529C>T p.T510I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99308064; called by muse, mutect2, varscan2
- CYP4F22 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as rs745682521, COSV54108443; called by muse, mutect2
- DCC | c.3370C>T p.R1124C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547920182, COSV101473425, COSV71439721; called by muse, mutect2, varscan2
- DSP | c.8123C>T p.S2708L | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1194266904, COSV100673008; ClinVar: uncertain significance; called by muse, mutect2
- DUOX2 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV101199847, COSV66535250; called by muse, mutect2, varscan2
- EPHB6 | c.1955A>G p.Y652C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as rs1310626365, COSV100844380; called by muse, mutect2, varscan2
- FAM135A | c.2453C>G p.S818* (on ENST00000370479 / NM_001351599.1; = p.S605* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99526417; called by muse, mutect2, varscan2
- FAM83C | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs749884709, COSV100981594; called by muse, mutect2, varscan2
- FAM90A1 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV100274439; called by muse, mutect2, varscan2
- FAT1 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101499520, COSV101499582; called by muse, mutect2, varscan2
- FAT2 | c.1668C>G p.N556K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55822213, COSV99943759; called by muse, mutect2, varscan2
- FBXL20 | c.43-2A>G p.X15_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99234550; called by muse, mutect2, varscan2
- FCHSD2 | c.1760C>G p.S587C | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100238869; called by muse, mutect2
- FLG | c.5177C>A p.S1726* | Nonsense Mutation (SNP) | VAF 80/318 reads (25%) | catalogued as COSV100911675, COSV100911911; called by muse, mutect2, varscan2
- FNDC3A | c.938C>G p.S313* (on ENST00000492622 / NM_001079673.2; = p.S257* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 4/57 reads (7%) | catalogued as COSV101001325; called by muse, mutect2
- GPSM3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV100900832; called by muse, mutect2, varscan2
- GRIA2 | c.977A>T p.N326I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV52382861; called by muse, mutect2
- HAVCR1 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV100208486; called by muse, mutect2
- HCN1 | c.2164C>G p.P722A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.084); catalogued as COSV100297694, COSV100301521, COSV57521384; called by muse, varscan2
- HIRIP3 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 23/324 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV99663238; called by muse, mutect2
- INTS6L | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.163); catalogued as COSV100878219, COSV100878313; called by muse, mutect2, varscan2
- IRX4 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV51475136; called by muse, mutect2
- ITPR2 | c.7430G>A p.R2477K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); catalogued as COSV101190095; called by muse, mutect2, varscan2
- IZUMO1R | c.540G>C p.E180D (on ENST00000440961; = p.E187D on NM_001199206.3) | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1202831386, COSV100126916; called by muse, mutect2
- KCNA6 | c.255C>G p.F85L | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768830; called by muse, mutect2
- KRTAP12-3 | c.85A>T p.S29C | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV100554833; called by muse, mutect2, varscan2
- LCLAT1 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV100474627; called by muse, mutect2
- LILRB2 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV100079103; called by muse, mutect2, varscan2
- LIN7B | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55521943; called by muse, mutect2, varscan2
- LRP12 | c.1729A>T p.N577Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99408111; called by muse, mutect2, varscan2
- LRRC66 | c.2297G>T p.C766F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs753292616, COSV100603039; called by muse, mutect2, varscan2
- LRRTM4 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV101297661; called by muse, mutect2, varscan2
- LSMEM1 | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1263048617, COSV100456297; called by muse, mutect2
- MARCHF7 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99373979; called by muse, mutect2
- MED29 | c.309G>T p.L103F (on ENST00000615911; = p.L82F on NM_017592.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV99655962; called by muse, mutect2, varscan2
- MLKL | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV100087412; called by muse, mutect2
- MMP10 | c.1203C>G p.F401L | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54246960, COSV99666684; called by muse, mutect2
- NEK5 | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1445430244, COSV100839274; called by muse, mutect2
- NFRKB | c.3080G>C p.S1027T (on ENST00000446488 / NM_001143835.2; = p.S1052T on NM_006165.3) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.258); catalogued as COSV100452039; called by muse, mutect2
- NID2 | c.1372T>G p.L458V | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99357008; called by muse, mutect2, varscan2
- NOC3L | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64929687; called by muse, mutect2
- NRP2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV55925090; called by muse, mutect2
- OR14C36 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100507605, COSV58602117; called by muse, mutect2, varscan2
- OR2G6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV100598272; called by muse, mutect2
- OR51L1 | c.600T>A p.Y200* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100386464; called by muse, mutect2, varscan2
- OR5AK2 | c.323C>G p.A108G | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV100476108, COSV100476179; called by muse, mutect2, varscan2
- OR6N1 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625235, COSV100625267; called by muse, mutect2
- PAF1 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as COSV99655961; called by muse, mutect2
- PARP2 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51639040; called by muse, mutect2
- PCARE | c.1539G>T p.R513S | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100527765; called by muse, mutect2, varscan2
- PCDHA5 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as rs1317473064, COSV65358199; called by muse, mutect2, varscan2
- PDE8B | c.1167+1G>C p.X389_splice | Splice Site (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99367281; called by muse, mutect2
- PDK3 | c.354A>T p.R118S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100998187; called by muse, mutect2, varscan2
- PKD1L1 | c.689A>T p.Q230L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV99220883; called by muse, mutect2, varscan2
- PLCD1 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99379123; called by muse, mutect2, varscan2
- PLEKHG4B | c.3463G>T p.D1155Y (on ENST00000283426; = p.D1511Y on NM_052909.5) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs374979115, COSV52054712, COSV99360805; called by muse, mutect2
- POU6F1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1565600390, COSV100374871; called by muse, mutect2
- PPP2R2C | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100160776, COSV59443262; called by muse, mutect2
- PRDM10 | c.1828C>G p.H610D | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100456917; called by muse, mutect2, varscan2
- PTTG1IP | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs188877011, COSV100445940; called by mutect2, varscan2
- RC3H1 | c.2055G>C p.E685D | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99281624; called by muse, mutect2
- REXO1 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs767053522, COSV99402536; called by muse, mutect2, varscan2
- REXO5 | c.881A>G p.Q294R | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99759364; called by muse, mutect2
- RPL10L | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100022668; called by mutect2, varscan2
- RPS15A | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV100540011; called by muse, mutect2, varscan2
- SLC17A6 | c.788T>A p.V263E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV99582047; called by muse, mutect2, varscan2
- SLC25A36 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV100149179; called by muse, mutect2, varscan2
- SLC6A14 | c.1056G>C p.L352F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV100903190; called by mutect2, varscan2
- SNPH | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.07); catalogued as rs144751280; called by muse, mutect2, varscan2
- SNX25 | c.2378G>C p.R793P | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53016794, COSV99253275; called by muse, mutect2
- SPTBN4 | c.5085C>T p.S1695= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs752966472, COSV100151683; called by muse, mutect2
- SQOR | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99526020; called by muse, mutect2, varscan2
- STRADB | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99524697; called by muse, mutect2
- TAF1L | c.4324C>T p.R1442W | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs773657347, COSV99645169; called by muse, mutect2, varscan2
- TCTN1 | c.1661C>T p.A554V (on ENST00000551590 / NM_001173975.3; = p.A540V on NM_024549.6) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs373723058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIGD7 | c.539C>G p.T180R | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99239946; called by muse, mutect2, varscan2
- TLL2 | c.965A>T p.N322I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV63575853; called by muse, mutect2, varscan2
- TMTC2 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100338567; called by muse, mutect2
- TMTC3 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780431621, COSV99898556; called by muse, mutect2, varscan2
- TRPS1 | c.1495G>C p.D499H (on ENST00000220888 / NM_001330599.2; = p.D512H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); catalogued as COSV99632992; called by muse, mutect2
- TUT7 | c.3264A>T p.R1088S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99463411; called by muse, varscan2
- UACA | c.1851A>T p.K617N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV100537636; called by muse, mutect2
- UBE4B | c.2029G>C p.D677H (on ENST00000343090 / NM_001105562.3; = p.D548H on NM_006048.5) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99477351; called by muse, mutect2
- USP28 | c.1991C>G p.S664* | Nonsense Mutation (SNP) | VAF 16/286 reads (6%) | catalogued as rs1415315229, COSV99136101; called by muse, mutect2
- XPO5 | c.3437G>A p.R1146Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs765690738, COSV54831817; called by muse, mutect2, varscan2
- XYLT1 | c.2600A>T p.Y867F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99762825; called by muse, varscan2
- ZBTB11 | c.2941C>G p.Q981E | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs964275700, COSV100465697; called by muse, mutect2, varscan2
- ZNF23 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV100612230; called by muse, mutect2, varscan2
- ZNF257 | c.1121G>A p.C374Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101448144; called by muse, mutect2, varscan2
- ZNF544 | c.140G>A p.W47* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as COSV99517179; called by muse, mutect2, varscan2
- ZSCAN20 | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100792694; called by muse, mutect2, varscan2
- ZSCAN20 | c.1678C>G p.P560A | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.072); catalogued as COSV100792696; called by muse, mutect2
- ZSCAN20 | c.2420C>G p.S807* | Nonsense Mutation (SNP) | VAF 14/160 reads (9%) | catalogued as rs756611770, COSV100792700; called by muse, mutect2
- SPATA31D1 | c.2684_2691del p.L895Qfs*11 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- VGLL3 | c.582G>C p.Q194H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.635); called by muse, mutect2
- CNTNAP2 | c.1128C>G p.V376= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100662290, COSV100669153; called by muse, mutect2, varscan2
- CYP27B1 | c.45C>T p.V15= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV99141614; called by muse, mutect2
- DOCK4 | c.5784G>A p.P1928= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs904210669, COSV70237712, COSV70241957; called by muse, mutect2, varscan2
- FAM135B | c.1665C>T p.D555= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs757138084, COSV52753154; called by muse, mutect2, varscan2
- HBM | c.366A>G p.Q122= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs778893345, COSV100720797; called by mutect2, varscan2
- KIAA1755 | c.3462T>C p.L1154= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99642426; called by muse, mutect2, varscan2
- MAML2 | c.930C>T p.F310= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV73264945; called by muse, mutect2
- OR1L6 | c.495C>T p.N165= (on ENST00000373684; = p.N129= on NM_001004453.2) | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs768003046, COSV100490966; called by muse, mutect2
- OR2M2 | c.189C>T p.L63= | Silent (SNP) | VAF 14/399 reads (4%) | catalogued as rs1354156224, COSV100677284; called by muse, mutect2
- PEX2 | c.189C>T p.F63= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100824868; called by muse, mutect2
- PLCD4 | c.900C>T p.F300= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV101346935; called by muse, mutect2
- PLPP7 | c.312G>A p.A104= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs371251864; called by muse, mutect2, varscan2
- POLA2 | c.1785C>T p.V595= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs749335729, COSV99641161; called by muse, mutect2, varscan2
- PTPRD | c.3573T>C p.Y1191= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100645974; called by muse, mutect2
- REV3L | c.4056G>A p.T1352= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs188531900, COSV100725524; called by muse, mutect2, varscan2
- RNF113B | c.657T>C p.D219= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV99940400; called by muse, mutect2, varscan2
- RPTOR | c.498C>G p.V166= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100156887; called by muse, mutect2
- SLC4A9 | c.1287T>C p.T429= (on ENST00000507527 / NM_001258428.2; = p.T405= on NM_031467.3) | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99139488; called by muse, mutect2
- SNTG1 | c.1203T>C p.Y401= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV99385196; called by muse, mutect2
- SP3 | c.888G>A p.L296= | Silent (SNP) | VAF 9/184 reads (5%) | catalogued as COSV100022117; called by muse, mutect2
- SP3 | c.516G>A p.V172= | Silent (SNP) | VAF 13/304 reads (4%) | catalogued as COSV100022118; called by muse, mutect2
- ST18 | c.3084C>A p.S1028= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV52508699, COSV99390594; called by muse, mutect2, varscan2
- TAB3 | c.1191C>T p.H397= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99916574; called by muse, mutect2, varscan2
- TFB2M | c.1080G>A p.E360= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100830505; called by muse, mutect2
- UTP11 | c.453C>T p.V151= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs1020653905, COSV100884969; called by muse, mutect2
- VCAM1 | c.2100C>T p.L700= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as rs757752398, COSV99658788; called by muse, mutect2, varscan2
- ZNF606 | c.2019T>A p.I673= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100071922; called by muse, mutect2, varscan2
- C16orf82 | c.-37C>G | 5'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- NBPF7 | n.259G>T | RNA (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- RN7SL176P | chr12:100157723 G>C | 3'Flank (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
